Somatic mutation profile of tumor specimen MP2PRT-PAUTWU-TMP1-A (aliquot MP2PRT-PAUTWU-TMP1-A-1-0-D-A819-36) from MP2PRT case MP2PRT-PAUTWU, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: female; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 5.1 years (1,864 days).
Specimen MP2PRT-PAUTWU-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 98971a51-7df5-4e15-904c-0a8ee335dd0f.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PAUTWU-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PAUTWU-NB1-A-1-0-D-A819-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/9e7c69ec-0993-4d31-b4a8-7151fedc84b7

The open-access MAF lists 37 somatic variants for this specimen: 28 protein-altering or splice-affecting, 9 silent.
By variant classification: Missense Mutation 26, Silent 9, Nonsense Mutation 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ACTC1 | c.553C>T p.R185W | Missense Mutation (SNP) | VAF 119/263 reads (45%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.951); catalogued as rs397517065, COSV51762486; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- FLT3 | c.2508_2510del p.I836del | In Frame Del (DEL) | VAF 70/169 reads (41%) | catalogued as rs121913490; ClinVar: likely pathogenic; called by mutect2, pindel, varscan2
- XPO1 | c.1711G>A p.E571K | Missense Mutation (SNP) | VAF 91/227 reads (40%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1057520009, COSV68944533, COSV68945324; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- C8orf34 | c.196C>T p.P66S | Missense Mutation (SNP) | VAF 231/480 reads (48%) | SIFT deleterious, low confidence (0.02); catalogued as rs1379721358; called by muse, mutect2, varscan2
- F8 | c.1745G>C p.G582A | Missense Mutation (SNP) | VAF 82/303 reads (27%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as CM062668, CM070104, CM145558, COSV64273953; called by muse, mutect2, varscan2
- KIAA0513 | c.632C>T p.S211F | Missense Mutation (SNP) | VAF 188/422 reads (45%) | SIFT deleterious (0); PolyPhen benign (0.143); catalogued as rs752373730, COSV99075383; called by muse, mutect2, varscan2
- KLB | c.1271G>A p.R424H | Missense Mutation (SNP) | VAF 182/485 reads (38%) | SIFT tolerated (0.87); PolyPhen benign (0); catalogued as rs369568090, COSV57300324; called by muse, mutect2, varscan2
- LAMA2 | c.3977G>A p.R1326Q | Missense Mutation (SNP) | VAF 88/374 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs748257607, COSV70337596; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- LAMA2 | c.4448C>G p.S1483C | Missense Mutation (SNP) | VAF 108/330 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.8); catalogued as COSV70339338, COSV70352588; called by muse, mutect2, varscan2
- LCN15 | c.62A>C p.E21A | Missense Mutation (SNP) | VAF 136/318 reads (43%) | SIFT deleterious (0); PolyPhen benign (0.127); catalogued as COSV60209364; called by muse, mutect2, varscan2
- MYO15A | c.3058G>T p.D1020Y | Missense Mutation (SNP) | VAF 271/865 reads (31%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.26); catalogued as COSV52753225; called by muse, mutect2, varscan2
- RYR2 | c.11710C>T p.R3904W | Missense Mutation (SNP) | VAF 97/237 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.98); catalogued as rs998659755, COSV100773660, COSV63670026; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TLE7 | c.1178G>A p.R393H | Missense Mutation (SNP) | VAF 88/203 reads (43%) | SIFT tolerated (0.11); PolyPhen benign (0.068); catalogued as rs536508481; called by muse, mutect2, varscan2
- UGT8 | c.1267C>T p.R423C | Missense Mutation (SNP) | VAF 15/279 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as rs1373770804; called by muse, mutect2
- UNC80 | c.7009G>A p.E2337K | Missense Mutation (SNP) | VAF 138/334 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV55883032; called by muse, mutect2, varscan2
- WNK3 | c.1160G>A p.R387H | Missense Mutation (SNP) | VAF 103/411 reads (25%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.825); catalogued as rs782355785, COSV63615386; called by muse, mutect2, varscan2
- AADACL2 | c.352G>T p.G118* | Nonsense Mutation (SNP) | VAF 27/237 reads (11%) | called by muse, mutect2, varscan2
- ADAMTS6 | c.1432G>C p.V478L | Missense Mutation (SNP) | VAF 192/337 reads (57%) | SIFT deleterious (0.04); PolyPhen benign (0.313); called by muse, mutect2, varscan2
- C8orf34 | c.197C>T p.P66L | Missense Mutation (SNP) | VAF 231/481 reads (48%) | SIFT deleterious, low confidence (0); called by muse, mutect2, varscan2
- CIT | c.1013T>C p.I338T | Missense Mutation (SNP) | VAF 160/352 reads (45%) | SIFT deleterious (0); PolyPhen benign (0.375); called by muse, mutect2, varscan2
- CTNNA2 | c.1478T>A p.V493D | Missense Mutation (SNP) | VAF 134/332 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- GAL3ST3 | c.956G>A p.R319H | Missense Mutation (SNP) | VAF 115/204 reads (56%) | SIFT tolerated (0.07); PolyPhen benign (0.013); called by muse, varscan2
- KDR | c.1219G>A p.E407K | Missense Mutation (SNP) | VAF 264/397 reads (66%) | SIFT tolerated (0.3); PolyPhen possibly damaging (0.532); called by muse, mutect2, varscan2
- MEIOC | c.1198C>T p.H400Y | Missense Mutation (SNP) | VAF 141/501 reads (28%) | SIFT tolerated (0.99); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- RBBP8NL | c.850C>T p.P284S | Missense Mutation (SNP) | VAF 183/405 reads (45%) | SIFT tolerated (0.09); PolyPhen benign (0.142); called by muse, mutect2, varscan2
- SCD | c.206T>C p.V69A | Missense Mutation (SNP) | VAF 125/306 reads (41%) | SIFT tolerated (0.12); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- SPATC1 | c.1051C>T p.P351S | Missense Mutation (SNP) | VAF 160/367 reads (44%) | SIFT tolerated (0.23); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- TBC1D25 | c.558G>C p.W186C | Missense Mutation (SNP) | VAF 36/669 reads (5%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.829); called by muse, mutect2
- ARNT | c.468G>A p.P156= | Silent (SNP) | VAF 104/223 reads (47%) | catalogued as rs115636467; called by muse, mutect2, varscan2
- COL19A1 | c.1938A>T p.R646= | Silent (SNP) | VAF 11/359 reads (3%) | called by muse, mutect2
- ELOA3D | c.693C>T p.R231= | Silent (SNP) | VAF 188/956 reads (20%) | catalogued as rs779922091, COSV55300867; called by muse, mutect2, varscan2
- FAM189A1 | c.1518C>T p.T506= | Silent (SNP) | VAF 174/358 reads (49%) | catalogued as rs942091049; called by muse, mutect2, varscan2
- LMOD1 | c.1113C>T p.A371= | Silent (SNP) | VAF 166/365 reads (45%) | catalogued as rs772006489, COSV66173592; ClinVar: likely benign; called by muse, mutect2, varscan2
- MAGEC1 | c.1968C>T p.V656= | Silent (SNP) | VAF 227/783 reads (29%) | catalogued as rs757152775; called by muse, mutect2, varscan2
- NPNT | c.396C>T p.T132= | Silent (SNP) | VAF 97/326 reads (30%) | called by muse, mutect2, varscan2
- TTK | c.2322G>A p.R774= | Silent (SNP) | VAF 98/347 reads (28%) | catalogued as rs1040350528; called by muse, mutect2, varscan2
- ZBTB18 | c.684C>T p.T228= | Silent (SNP) | VAF 130/313 reads (42%) | called by muse, mutect2, varscan2
